Somatic mutation profile of tumor specimen C3L-01683-01 (aliquot CPT0110980010) from CPTAC case C3L-01683, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 77.8 years (28,432 days).
Specimen C3L-01683-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 139a6340-7f96-4732-b464-ca06ced1d30d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01683-31 (Blood Derived Normal), aliquot CPT0112390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4dc43d0-2fea-49ee-8717-629b9c9e6cbb

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDYL | c.371G>T p.R124I (on ENST00000328908 / NM_001368125.1; = p.R70I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/493 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV59359335; called by muse, mutect2
- KCNA1 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV101230299; called by muse, mutect2
- LCP2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 10/298 reads (3%) | catalogued as COSV50456273; called by muse, mutect2
- MICAL1 | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100668623; called by muse, mutect2
- MYH9 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 18/447 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV53394242; called by muse, mutect2
- PRDM8 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1040018641; called by muse, mutect2
- TMEM61 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64873404; called by muse, mutect2
- ADIPOR1 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.402); called by muse, mutect2
- DAZL | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2
- DMD | c.10421A>C p.H3474P | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- GLI3 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- L3MBTL3 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- LRP1 | c.9215A>T p.Y3072F | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MAGEA8 | c.717C>A p.H239Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); called by muse, mutect2
- NCL | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- RNF14 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- SPAST | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2
- ARMCX4 | c.816G>A p.K272= (on ENST00000433011; = p.K168= on NM_001256155.2) | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as rs1167280832; called by muse, mutect2
- DAZL | c.783T>C p.N261= | Silent (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- GML | c.120C>T p.F40= | Silent (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- POM121L12 | c.735C>G p.L245= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as COSV101374895, COSV68693088; called by muse, mutect2
- DCAF12L1 | c.-1C>A | 5'UTR (SNP) | VAF 12/164 reads (7%) | catalogued as COSV64421102; called by muse, mutect2
- SDHB | c.*14A>C | 3'UTR (SNP) | VAF 10/298 reads (3%) | called by muse, mutect2
